Somatic mutation profile of tumor specimen 0DXHA8 from CCDI case PAUTVR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.6 years (577 days).
Specimen 0DXHA8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 691bf86c-2995-4a46-9f27-2120149712a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXH9I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19855833-afab-471c-80d9-e7f3e07d7916

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 16, Splice Site 6, Intron 5, Nonsense Mutation 4, 3'UTR 3, Splice Region 2, Frame Shift Del 1, 5'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 108/510 reads (21%) | catalogued as rs886041538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AOX1 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 533/1154 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866567689; called by muse, mutect2, varscan2
- EHBP1L1 | c.312+4_312+7del p.X104_splice | Splice Site (DEL) | VAF 386/1046 reads (37%) | catalogued as rs1441423753; called by mutect2, pindel, varscan2
- EPPK1 | c.15014G>A p.R5005H | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs782283437; called by muse, mutect2, varscan2
- ERBB3 | c.2785C>T p.R929W | Missense Mutation (SNP) | VAF 316/763 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759764423; called by muse, mutect2, varscan2
- FRG1 | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 119/1486 reads (8%) | catalogued as rs76810924, COSV57008837; called by muse, mutect2
- GPR158 | c.2366G>T p.R789M | Missense Mutation (SNP) | VAF 108/1404 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV66266996, COSV66270584; called by muse, mutect2
- INPP4A | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 275/991 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50788765; called by muse, mutect2, varscan2
- KRTAP4-3 | c.418T>C p.Y140H | Missense Mutation (SNP) | VAF 265/470 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); catalogued as rs1472687217; called by muse, mutect2, varscan2
- LIG4 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 55/940 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV100799901; called by muse, mutect2
- MSH4 | c.2643G>T p.E881D | Missense Mutation (SNP) | VAF 342/673 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs1329978315, COSV54207257; called by muse, mutect2, varscan2
- OR5M10 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 164/625 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1201103677; called by muse, mutect2, varscan2
- SGO2 | c.3340G>C p.D1114H | Missense Mutation (SNP) | VAF 80/1764 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV63418280; called by muse, mutect2
- SLC20A2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 138/520 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as CM1410693, COSV100646040; called by muse, mutect2, varscan2
- SLC5A8 | c.389G>C p.C130S | Missense Mutation (SNP) | VAF 34/998 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1486965175; called by muse, mutect2
- SYMPK | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 263/514 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55610149; called by muse, mutect2, varscan2
- TAF10 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 574/1326 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs763522406; called by muse, mutect2
- TSC1 | c.2503-1G>A p.X835_splice | Splice Site (SNP) | VAF 64/762 reads (8%) | catalogued as CS001851, CS052419, CS971918, COSV53766195; called by muse, mutect2
- TXNDC5 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 31/263 reads (12%) | catalogued as rs377761794; called by muse, mutect2, varscan2
- ARHGEF37 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 66/367 reads (18%) | called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 45/1269 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CA4 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 214/705 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CAPRIN2 | c.3226C>G p.Q1076E | Missense Mutation (SNP) | VAF 108/1178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CEP170 | c.1861T>C p.S621P | Missense Mutation (SNP) | VAF 118/1552 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2
- CKAP5 | c.4568+1G>A p.X1523_splice | Splice Site (SNP) | VAF 325/718 reads (45%) | called by muse, mutect2, varscan2
- COBLL1 | c.3451A>T p.S1151C (on ENST00000392717; = p.S1113C on NM_014900.5) | Missense Mutation (SNP) | VAF 67/1970 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2
- COL6A3 | c.3988A>T p.S1330C | Missense Mutation (SNP) | VAF 176/576 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPPED1 | c.72A>G p.E24= | Splice Region (SNP) | VAF 46/514 reads (9%) | called by muse, mutect2
- EGFR | c.1548G>T p.W516C | Missense Mutation (SNP) | VAF 449/2395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 62/828 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.3629A>C p.Q1210P | Missense Mutation (SNP) | VAF 245/1061 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLS | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 401/896 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRASP1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 591/623 reads (95%) | called by muse, mutect2, varscan2
- HRNR | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 245/1070 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- IDH1 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 526/1182 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ITIH5 | c.1419-2A>G p.X473_splice | Splice Site (SNP) | VAF 60/479 reads (13%) | called by muse, mutect2, varscan2
- KLHL42 | c.1298A>G p.E433G | Missense Mutation (SNP) | VAF 326/796 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- LMTK3 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 142/508 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2K2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 82/489 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRPL4 | c.409_421delinsG p.R137_I141delinsV | In Frame Del (DEL) | VAF 174/629 reads (28%) | called by pindel, varscan2*
- NIBAN3 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 36/714 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2
- NPRL2 | c.683+4A>G | Splice Region (SNP) | VAF 246/436 reads (56%) | called by muse, mutect2, varscan2
- NR2E3 | c.1200G>T p.M400I | Missense Mutation (SNP) | VAF 362/1211 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- OR10J5 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 345/2227 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4S2 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 604/1272 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR5M11 | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 351/1283 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR9A4 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 674/2213 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OSBPL11 | c.805A>G p.N269D | Missense Mutation (SNP) | VAF 28/848 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2
- PDE4A | c.1162G>C p.G388R (on ENST00000380702 / NM_001111307.2; = p.G149R on NM_006202.3) | Missense Mutation (SNP) | VAF 358/807 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PLEKHA8 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 484/1638 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- POLE2 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 257/274 reads (94%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, varscan2
- PSIP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 105/531 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- RBP3 | c.886T>C p.W296R | Missense Mutation (SNP) | VAF 24/744 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC29A4 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 158/867 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC4A11 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 270/608 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SOX11 | c.1297A>G p.N433D | Missense Mutation (SNP) | VAF 628/1294 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SPTLC3 | c.1454T>A p.V485E | Missense Mutation (SNP) | VAF 126/1003 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STRN3 | c.986G>C p.W329S | Missense Mutation (SNP) | VAF 476/510 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SYCP2 | c.2600+1G>T p.X867_splice | Splice Site (SNP) | VAF 252/842 reads (30%) | called by mutect2, varscan2
- THADA | c.3440A>G p.K1147R | Missense Mutation (SNP) | VAF 183/1448 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM249 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 394/428 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TNFRSF13B | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TNRC6C | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 208/578 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TONSL | c.1923G>T p.W641C | Missense Mutation (SNP) | VAF 224/341 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSC1 | c.2767_2770del p.L923Wfs*7 | Frame Shift Del (DEL) | VAF 330/632 reads (52%) | called by pindel, varscan2
- ZFAND3 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 499/548 reads (91%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIM2 | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 302/916 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF646 | c.2239C>A p.H747N | Missense Mutation (SNP) | VAF 317/780 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AHNAK2 | c.14712C>T p.C4904= | Silent (SNP) | VAF 72/317 reads (23%) | called by muse, mutect2, varscan2
- BRIX1 | c.24G>C p.R8= | Silent (SNP) | VAF 117/511 reads (23%) | catalogued as COSV57715293; called by muse, mutect2, varscan2
- CD177 | c.1104C>T p.S368= | Silent (SNP) | VAF 260/677 reads (38%) | called by muse, mutect2, varscan2
- CSMD3 | c.3408G>A p.L1136= (on ENST00000297405 / NM_001363185.1; = p.L1032= on NM_052900.3) | Silent (SNP) | VAF 709/783 reads (91%) | called by muse, mutect2, varscan2
- FAM186B | c.1593G>A p.Q531= | Silent (SNP) | VAF 508/1029 reads (49%) | called by muse, mutect2, varscan2
- FYCO1 | c.3399C>G p.T1133= | Silent (SNP) | VAF 95/656 reads (14%) | catalogued as COSV56116035; called by muse, mutect2, varscan2
- GREB1L | c.4185G>A p.L1395= | Silent (SNP) | VAF 271/1040 reads (26%) | called by muse, mutect2, varscan2
- H2AC21 | c.39T>C p.A13= | Silent (SNP) | VAF 109/2186 reads (5%) | catalogued as rs1278118495, COSV58611635; called by muse, mutect2
- KIF26B | c.1548C>T p.D516= | Silent (SNP) | VAF 408/1591 reads (26%) | catalogued as rs368089035; called by muse, mutect2, varscan2
- MGAM2 | c.174G>A p.Q58= | Silent (SNP) | VAF 78/2142 reads (4%) | catalogued as rs1216651462, COSV72176639; called by muse, mutect2
- NOTCH1 | c.6129C>T p.A2043= | Silent (SNP) | VAF 498/524 reads (95%) | catalogued as rs563053477; called by muse, varscan2
- OR6C75 | c.222C>T p.V74= | Silent (SNP) | VAF 279/1004 reads (28%) | called by muse, mutect2, varscan2
- PRRX2 | c.162G>C p.R54= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- RTP5 | c.849C>T p.F283= | Silent (SNP) | VAF 145/917 reads (16%) | catalogued as rs780147230, COSV58320748; called by muse, mutect2, varscan2
- WDR26 | c.540T>A p.V180= (on ENST00000414423 / NM_001379403.1; = p.V80= on NM_025160.7) | Silent (SNP) | VAF 187/1312 reads (14%) | called by muse, mutect2, varscan2
- ZNF775 | c.1326G>A p.E442= | Silent (SNP) | VAF 132/740 reads (18%) | called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 10/204 reads (5%) | catalogued as rs1262556378; called by muse, mutect2
- ARHGAP21 | c.4044+63G>A | Intron (SNP) | VAF 379/852 reads (44%) | catalogued as rs1264739683; called by muse, mutect2, varscan2
- CRNDE | n.1641G>A | RNA (SNP) | VAF 660/1415 reads (47%) | called by muse, mutect2, varscan2
- EEF1AKMT2 | c.*47G>C | 3'UTR (SNP) | VAF 46/1666 reads (3%) | called by muse, mutect2
- MKRN3 | c.*28T>G | 3'UTR (SNP) | VAF 62/702 reads (9%) | called by muse, mutect2
- MPP1 | c.103-22C>A | Intron (SNP) | VAF 514/546 reads (94%) | called by muse, varscan2
- MPZL2 | c.59-41C>T | Intron (SNP) | VAF 95/330 reads (29%) | catalogued as rs769343104; called by muse, mutect2, varscan2
- MTR | c.3405+21C>T | Intron (SNP) | VAF 241/1473 reads (16%) | catalogued as rs750486662, COSV63965013; called by muse, mutect2, varscan2
- TSSC4 | c.-16G>A | 5'UTR (SNP) | VAF 107/317 reads (34%) | catalogued as rs371191108; called by muse, mutect2, varscan2
- UNG | c.*53T>G | 3'UTR (SNP) | VAF 22/357 reads (6%) | called by muse, mutect2
